Somatic mutation profile of cancer-model specimen HCM-CSHL-1263-C24-85M (3D Organoid; aliquot HCM-CSHL-1263-C24-85M-01D-A88H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-1263-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 76.7 years (28,014 days).
Specimen HCM-CSHL-1263-C24-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e86bdbf7-04a6-424a-a0f1-1d42a6458cda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-1263-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-1263-C24-10A-01D-A88H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36ea8bba-71ae-4024-910b-4afbc37e4062

The open-access MAF lists 88 somatic variants for this specimen: 61 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 24, Nonsense Mutation 4, Frame Shift Del 2, Intron 2, Splice Site 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.6380C>G p.S2127* | Nonsense Mutation (SNP) | VAF 332/533 reads (62%) | catalogued as COSV53770009; called by muse, mutect2, varscan2
- BAP1 | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 272/273 reads (100%) | catalogued as COSV56239857, COSV56240952; called by muse, mutect2, varscan2
- BSN | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 42/658 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.296); catalogued as rs372598293, COSV56528908; called by muse, mutect2
- CASP8 | c.1015C>T p.Q339* (on ENST00000432109 / NM_033355.3; = p.Q356* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 19/462 reads (4%) | catalogued as COSV51852083; called by muse, mutect2
- DIDO1 | c.2914C>T p.P972S | Missense Mutation (SNP) | VAF 229/702 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV56614074; called by muse, mutect2, varscan2
- DNAH10 | c.6500G>A p.R2167H (on ENST00000409039; = p.R2106H on NM_207437.3) | Missense Mutation (SNP) | VAF 38/807 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs766596956, COSV68988967; called by muse, mutect2
- EYS | c.1666C>T p.L556F | Missense Mutation (SNP) | VAF 248/248 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.198); catalogued as COSV60978789; called by muse, mutect2, varscan2
- GALE | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 403/404 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs765353795, CM060014; called by muse, mutect2, varscan2
- ITGA3 | c.2600C>A p.P867Q | Missense Mutation (SNP) | VAF 123/610 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.882); catalogued as rs1043973764; called by muse, mutect2, varscan2
- KIF6 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 163/397 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749063566, COSV54666093; called by muse, mutect2, varscan2
- LATS1 | c.2917C>A p.P973T | Missense Mutation (SNP) | VAF 134/261 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV53587536; called by muse, mutect2, varscan2
- LRP3 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 549/549 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs768597836; called by muse, mutect2, varscan2
- MAP2 | c.1047C>G p.D349E | Missense Mutation (SNP) | VAF 139/499 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.097); catalogued as rs777032891; called by muse, mutect2, varscan2
- NF1 | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as CS086356, COSV62204363; called by muse, varscan2
- NTN5 | c.408C>G p.S136R | Missense Mutation (SNP) | VAF 78/942 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54306624; called by muse, mutect2
- OCRL | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV104420302; called by muse, mutect2, varscan2
- PGLYRP2 | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 172/523 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV52991681; called by muse, mutect2, varscan2
- STEAP3 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 127/382 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1473184416; called by muse, mutect2, varscan2
- STRIP1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 44/642 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs762142372, COSV63929704; called by muse, mutect2
- TPP1 | c.1399C>T p.P467S | Missense Mutation (SNP) | VAF 158/577 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV54991672; called by muse, mutect2, varscan2
- WDR33 | c.2326C>G p.L776V | Missense Mutation (SNP) | VAF 274/428 reads (64%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.187); catalogued as COSV100459472; called by muse, mutect2, varscan2
- XPOT | c.2867T>C p.F956S | Missense Mutation (SNP) | VAF 15/375 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV59156517; called by muse, mutect2
- ZFHX3 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.659); catalogued as COSV51708575; called by muse, mutect2, varscan2
- ZNF236 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 82/240 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1238793913; called by muse, mutect2, varscan2
- AMHR2 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 502/503 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD61 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 90/404 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- BRWD3 | c.2509G>T p.V837L | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C21orf58 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 423/423 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CCT6A | c.380A>C p.K127T | Missense Mutation (SNP) | VAF 111/408 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CORIN | c.2222T>C p.I741T | Missense Mutation (SNP) | VAF 200/307 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DIP2B | c.388A>T p.T130S | Missense Mutation (SNP) | VAF 273/383 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DMXL2 | c.2873C>A p.S958Y | Missense Mutation (SNP) | VAF 125/377 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EGLN2 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 161/514 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML4 | c.1900-1G>T p.X634_splice | Splice Site (SNP) | VAF 99/501 reads (20%) | called by muse, mutect2, varscan2
- FOXN4 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 263/263 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- HMGXB3 | c.910del p.L304* (on ENST00000613459; = p.L58* on NM_014983.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 114/267 reads (43%) | called by mutect2, pindel, varscan2
- HSD11B1L | c.461C>A p.T154K | Missense Mutation (SNP) | VAF 31/532 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.219); called by muse, mutect2
- IDE | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT tolerated (0.57); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- IGHV3-66 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 195/403 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- INTS1 | c.1207A>C p.M403L | Missense Mutation (SNP) | VAF 250/546 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by mutect2, varscan2
- KTN1 | c.1351C>A p.L451I | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- METTL2B | c.817_819del p.K273del | In Frame Del (DEL) | VAF 70/386 reads (18%) | called by mutect2, pindel, varscan2
- MUC16 | c.43046A>G p.N14349S | Missense Mutation (SNP) | VAF 106/307 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- NF1 | c.1002C>G p.I334M | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, varscan2
- OR10G8 | c.266G>T p.R89M | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- OR6C1 | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 100/1308 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCNT | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 165/408 reads (40%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, varscan2
- PDXK | c.161del p.G54Afs*4 | Frame Shift Del (DEL) | VAF 70/612 reads (11%) | called by mutect2, pindel, varscan2
- PLIN4 | c.2536G>C p.G846R (on ENST00000301286; = p.G861R on NM_001367868.2) | Missense Mutation (SNP) | VAF 394/395 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- POLE | c.5857G>T p.E1953* | Nonsense Mutation (SNP) | VAF 159/667 reads (24%) | called by muse, mutect2, varscan2
- PSMD4 | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 203/293 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PSMD4 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 321/443 reads (72%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- QARS1 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- RRNAD1 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 206/806 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A1 | c.1573G>C p.A525P | Missense Mutation (SNP) | VAF 356/357 reads (100%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THNSL1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 137/137 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TMC2 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- UPK3BL1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 71/387 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- UROD | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 327/481 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- USP17L7 | c.563A>C p.K188T | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ZNF131 | c.1100G>C p.R367T (on ENST00000509156 / NM_001330707.2; = p.R333T on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/288 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ANO4 | c.807A>G p.Q269= (on ENST00000392977 / NM_001286615.2; = p.Q234= on NM_178826.4) | Silent (SNP) | VAF 86/350 reads (25%) | called by muse, mutect2, varscan2
- ATP11A | c.2001G>A p.E667= | Silent (SNP) | VAF 213/214 reads (100%) | called by muse, mutect2, varscan2
- CADM1 | c.1092T>C p.G364= | Silent (SNP) | VAF 83/205 reads (40%) | called by muse, mutect2, varscan2
- CBLN4 | c.189G>T p.S63= | Silent (SNP) | VAF 196/639 reads (31%) | called by muse, mutect2, varscan2
- CDH5 | c.930A>G p.T310= | Silent (SNP) | VAF 52/329 reads (16%) | called by muse, mutect2, varscan2
- CEP126 | c.432C>G p.L144= | Silent (SNP) | VAF 704/892 reads (79%) | catalogued as COSV54830063; called by muse, mutect2, varscan2
- CYTH1 | c.1155C>T p.L385= | Silent (SNP) | VAF 141/597 reads (24%) | catalogued as rs1394463802, COSV100739264; called by muse, mutect2, varscan2
- ELFN2 | c.1647C>T p.N549= | Silent (SNP) | VAF 48/363 reads (13%) | called by muse, mutect2, varscan2
- FASTKD2 | c.1098C>T p.C366= | Silent (SNP) | VAF 105/288 reads (36%) | called by muse, mutect2, varscan2
- GLI3 | c.3186G>A p.S1062= | Silent (SNP) | VAF 259/587 reads (44%) | catalogued as rs747635516, COSV67885475; called by muse, mutect2, varscan2
- IQCF2 | c.9T>G p.V3= | Silent (SNP) | VAF 15/312 reads (5%) | called by muse, mutect2
- KCNT1 | c.1632C>T p.H544= (on ENST00000488444; = p.H563= on NM_020822.3) | Silent (SNP) | VAF 362/363 reads (100%) | catalogued as rs765616016; called by muse, mutect2, varscan2
- LHX8 | c.651A>G p.Q217= | Silent (SNP) | VAF 162/486 reads (33%) | called by muse, mutect2, varscan2
- LYPLAL1 | c.324A>G p.E108= | Silent (SNP) | VAF 91/245 reads (37%) | catalogued as rs754614121; called by muse, mutect2, varscan2
- NF1 | c.1254C>A p.I418= | Silent (SNP) | VAF 188/188 reads (100%) | catalogued as COSV100648151; called by muse, varscan2
- PIGT | c.1549C>T p.L517= | Silent (SNP) | VAF 166/495 reads (34%) | catalogued as rs991934492; called by muse, mutect2, varscan2
- PKD1L2 | c.2667G>A p.E889= | Silent (SNP) | VAF 191/397 reads (48%) | catalogued as COSV55167933; called by muse, mutect2, varscan2
- PPP1R12A | c.1344A>G p.A448= | Silent (SNP) | VAF 254/349 reads (73%) | catalogued as rs1239379678; called by muse, mutect2, varscan2
- RRNAD1 | c.870G>A p.L290= | Silent (SNP) | VAF 200/697 reads (29%) | catalogued as COSV100836954, COSV100836973; called by muse, mutect2, varscan2
- SHROOM1 | c.378G>A p.A126= | Silent (SNP) | VAF 188/299 reads (63%) | called by muse, mutect2, varscan2
- SYNM | c.1374C>T p.P458= | Silent (SNP) | VAF 224/368 reads (61%) | catalogued as rs782447126, COSV100152633; called by muse, mutect2, varscan2
- UBXN6 | c.237C>T p.I79= | Silent (SNP) | VAF 254/254 reads (100%) | catalogued as COSV56678354, COSV56680177; called by muse, mutect2, varscan2
- ZCCHC14 | c.1095C>T p.P365= (on ENST00000268616; = p.P502= on NM_015144.3) | Silent (SNP) | VAF 180/420 reads (43%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.78C>T p.P26= | Silent (SNP) | VAF 105/347 reads (30%) | catalogued as rs1207976865; called by muse, mutect2, varscan2
- DLX5 | c.540+27A>T | Intron (SNP) | VAF 195/802 reads (24%) | called by muse, mutect2, varscan2
- DSCR4 | n.111G>A | RNA (SNP) | VAF 27/160 reads (17%) | catalogued as rs369438551; called by muse, mutect2, varscan2
- PBX3 | c.844-11246G>A | Intron (SNP) | VAF 126/277 reads (45%) | catalogued as rs980073368; called by muse, mutect2, varscan2
